Surgical pathology report (de-identified scan), TCGA case TCGA-24-0970, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-0970-01B (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT FINAL

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

UTERUS, TOTAL ABDOMINAL HYSTERECTOMY

PAPILLARY SEROUS CARCINOMA, POORLY DIFFERENTIATED INVOLVING CORPUS AND
CERVICAL MYOMETRIUM, AND SEROSA WITH EXTENSIVE LYMPHOVASCULAR SPACE INVASION
- INACTIVE ENDOMETRIUM
- CERVIX WITH MUCOSAL ATROPHY

SOFT TISSUE, PARAMETRIUM, RIGHT AND LEFT, EXCISION

- PAPILLARY SEROUS CARCINOMA WITH EXTENSIVE LYMPHOVASCULAR SPACE INVASION
OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- PAPILLARY SEROUS CARCINOMA INVOLVING STROMA AND SURFACE
FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- PAPILLARY SEROUS CARCINOMA INVOLVING STROMA AND PERITUBAL SOFT TISSUES
OVARY, LEFT, SALPINGO-OOPHORECTOMY

- PAPILLARY SEROUS CARCINOMA INVOLVING STROMA AND SURFACE
FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- PAPILLARY SEROUS CARCINOMA INVOLVING TUBAL STROMA AND PERITUBAL SOFT
TISSUES

OMENTUM, EXCISION (INCLUDING FS1)

- PAPILLARY SEROUS CARCINOMA, POORLY DIFFERENTIATED
OMENTUM, GASTRIC COLIC, EXCISION

- PAPILLARY SEROUS CARCINOMA, POORLY DIFFERENTIATED (15 CM; SEE COMMENT)
SOFT TISSUE, RIGHT PERIRENAL MASS, EXCISION

- PAPILLARY SEROUS CARCINOMA, POORLY DIFFERENTIATED

By this signature, I attest that the above diagnosis is
based upon my personal
examination of the slides (and/or other material indicated in the
diagnosis).

***Report Electronically Reviewed and Signed Out By

*

[page 2 of 4]
Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up '#2, uterus, cervix, tubes and ovaries,' consisting of a radical hysterectomy specimen with a uterus measuring 8 x 6 x 4 cm. The posterior surface of the cervix has a small soft tissue fragment attached to it.

Opening the uterus reveals a smooth endometrial surface with no grossly identifiable lesion. The myometrium contains small leiomyomas. Dr. informed. All for permanents. By

FS1: Omentum, biopsy

- "Adenocarcinoma, consistent with Mullerian origin," by

Microscopic Description and Comment:

Histologic sections show extensive peritoneal tumor extension. The ovaries are normal in size, with multifocal involvement. The tumor may represent a primary peritoneal serous carcinoma.

History:

The patient is a year old woman with ovarian carcinoma and omental caking.

Operative procedure: Exploratory laparotomy with total abdominal hysterectomy and bilateral salpingo-oophorectomy.

Specimen(s) Received:

A: OMENTUM

B: HYSTERECTOMY, UTERUS, TUBES, OVARIES AND CERVIX

C: GASTRIC COLIC OMENTUM

D: RIGHT PERIRENAL MASS

Gross Description

The specimens are received in four formalin-filled containers, each labeled

The first container is labeled "omentum, FS1/X" and holds multiple pieces of fatty tissue measuring, in aggregate, 4.5 x 3.5 x 0.3 cm. The specimen appears to be diffusely infiltrated by fibrotic tissue suggesting tumor. Included in the container is a white cassette holding a piece of fatty tissue measuring 2.2 x 1 x 0.3 cm. Labeled A1 (FS1); A2, A3 - additional pieces of fatty tissue "X" Jar 1.

The second container is labeled "uterus, cervix, tubes and ovaries" and holds a uterus with bilateral adnexae weighing 172 grams. The uterine serosa is remarkable for the presence of multiple nodular lesions involving the anterior and posterior surface. The lesions appear to coalesce in some areas. They range in size from 1 to 0.7 cm in diameter. The right and left lateral portion of the uterus has been previously inked black. Small vessels are identified at this area; some may represent parametrial tissue. The parametrial tissue appears to be involved by fibrous indurated tissue, maybe representing tumor implants. The uterus measures 8 cm from superior to inferior, 6 cm in width and 4 cm from anterior to posterior. The cervix measures 0.5 cm in length and 4 cm in diameter. No vaginal cuff is grossly identified. The endocervix and lower uterine segment are grossly unremarkable. The uterine cavity is triangular in shape. The endometrium has an average thickness of 1 mm and no endometrial lesions are grossly identified. The myometrial thickness is 2.5 cm and an intramyometrial leiomyoma, measuring 0.6 cm, is identified toward the lateral left uterine wall. The left fallopian tube measures 3 cm in length and 0.4 cm in average circumference. The serosa is grossly unremarkable. The right ovary measures 3 x 1.5 x 1 cm. The stroma is gray-white and grossly unremarkable. The left fallopian tube measures 4.5 cm in length and 0.5 cm in average

[page 3 of 4]
diameter. On sectioning, the lumen is patent but a gray-white, fibrotic area suspicious for tumor involves the left fallopian tube. This area measures 2.5 x 1.5 x 0.9 cm. The left ovary measures 2.5 x 1.7 x 0.9 cm. On sectioning, the stroma is gray-white and unremarkable. Labeled B1 - right parametrial tissue; B2 - left parametrial tissue; B3 - anterior cervix; B4 - posterior cervix; B5 - anterior uterine wall; B6 - posterior uterine wall; B7 - anterior uterine wall, right side, with possible surface tumor implants; B8, B9 - anterior uterine wall, left side, with possible surface tumor implants; B10, B11 - posterior uterine wall with possible surface tumor implants; B12 - right fallopian tube and right ovary; B13, B14 - left fallopian tube with possible tumor implants, B14 includes left ovary. Jar 3.

The third container is labeled "gastrocolonic omentum" and holds multiple pieces of fatty tissue that are grossly consistent with an omentum. The specimen measures, in aggregate, 22 x 16 x 1.5 cm. The omentum appears to be diffusely infiltrated by gray-white tumor in an area that represents, upon reconstruction, a 15 x 12 x 0.8 cm. Labeled C1-C4. Jar 3.

The fourth container is labeled "right perirenal mass" and holds a piece of fibrous tissue measuring 3 x 1.5 x 0.9 cm. On sectioning, it appears to be diffusely infiltrated by tumor in all extension. Labeled D1. Jar 1.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The locations of the primary tumor(s) are the right and left ovary (synchronous primary tumors)

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor does invade the adjacent fallopian tube/peritubal soft tissue

TUMOR INVOLVEMENT

Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes cannot be assessed (NX)

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed (MX)

STAGE GROUPING

[page 4 of 4]
The Final AJCC/UICC/FIGO stage is T3c/N0/M0 (Stage IIIC)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 40b100cd-c294-4dae-bb61-a6d8c1f53d44 (TCGA-24-0970.50AB91D8-AEC6-46B6-95C1-8F008EE0ED8F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).